Somatic mutation profile of tumor specimen TARGET-30-PASXRG-01A (aliquot TARGET-30-PASXRG-01A-01D) from TARGET case TARGET-30-PASXRG, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 3.5 years (1,278 days).
Specimen TARGET-30-PASXRG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b432a51f-0e50-4f87-b9f5-4fee2a216c85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASXRG-10A (Blood Derived Normal), aliquot TARGET-30-PASXRG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e378e70-280f-41b2-bac9-0553222b5756

The open-access MAF lists 28 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 19, Silent 5, Nonsense Mutation 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASS | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62790933; called by muse, mutect2, varscan2
- ATMIN | c.510C>A p.C170* | Nonsense Mutation (SNP) | VAF 27/120 reads (23%) | catalogued as COSV55146939; called by muse, mutect2, varscan2
- ATP10B | c.1353G>T p.M451I | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.087); catalogued as COSV58779922; called by muse, mutect2, varscan2
- CHPF2 | c.1931C>T p.P644L | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs544098339, COSV50395559; called by muse, mutect2, varscan2
- CTNND2 | c.3523C>A p.Q1175K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.824); catalogued as COSV58907195; called by muse, mutect2, varscan2
- CYP2C9 | c.1129A>G p.R377G | Missense Mutation (SNP) | VAF 58/69 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV53246511; called by muse, mutect2, varscan2
- FANCM | c.4189A>C p.M1397L | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV57503982; called by muse, mutect2, varscan2
- GMCL1 | c.1534G>T p.E512* | Nonsense Mutation (SNP) | VAF 35/84 reads (42%) | catalogued as COSV57002682; called by muse, mutect2, varscan2
- JADE2 | c.1519C>A p.Q507K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.827); catalogued as COSV50923355; called by muse, mutect2, varscan2
- KRT1 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV52868133; called by muse, mutect2, varscan2
- LENG8 | c.2158C>T p.H720Y | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as rs778791903, COSV58729254; called by muse, mutect2, varscan2
- LRRIQ1 | c.4115C>T p.S1372F | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs747439668, COSV67827148, COSV67834565; called by muse, mutect2, varscan2
- MAPK9 | c.954C>G p.H318Q | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV58124078; called by muse, mutect2, varscan2
- MYF6 | c.468G>C p.K156N | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV57352601, COSV57353668; called by muse, mutect2, varscan2
- OBSCN | c.10087C>A p.H3363N | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.484); catalogued as COSV52802153; called by muse, mutect2, varscan2
- PDCD11 | c.574G>T p.G192C | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63934648; called by muse, mutect2, varscan2
- PROS1 | c.1544G>T p.R515L | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as CM992960, COSV67774691; called by muse, mutect2
- RUNDC1 | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64512267; called by muse, mutect2, varscan2
- SPATA16 | c.808A>G p.T270A | Missense Mutation (SNP) | VAF 70/135 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63531487; called by muse, mutect2, varscan2
- VANGL2 | c.1354A>T p.K452* | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | catalogued as COSV63604994; called by muse, mutect2, varscan2
- ZSWIM8 | c.5086del p.Y1696Tfs*17 (on ENST00000605216 / NM_001242487.2; = p.Y1701Tfs*17 on NM_015037.3) | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | catalogued as COSV55216547; called by mutect2, pindel, varscan2
- FAM83H | c.562C>T p.H188Y | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.111); called by muse, mutect2
- ZNF277 | c.181A>G p.I61V | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.038); called by muse, mutect2
- BCS1L | c.72T>C p.G24= | Silent (SNP) | VAF 9/123 reads (7%) | called by muse, mutect2
- CD163 | c.2280G>T p.L760= | Silent (SNP) | VAF 13/200 reads (7%) | called by muse, mutect2
- IFT140 | c.1029C>T p.T343= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs556379159, COSV68485725; called by muse, mutect2, varscan2
- IGF2BP1 | c.1308C>T p.S436= | Silent (SNP) | VAF 35/240 reads (15%) | catalogued as rs142465987; called by muse, mutect2, varscan2
- PRAMEF8 | c.1077G>T p.G359= | Silent (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2, varscan2
